Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A45R, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A45R-01A (Primary Tumor).

DOB:

Sex: M

Physician:

Accession:

Received

Pathologist:

Case type: Surgical History

** Case Imported from legacy computer system. The format of this report does not match the original case. **
** For cases prior to the section "SPECIMEN" may have been added. **

DIAGNOSIS

- (A) RIGHT SUPRAOMOHYOID NECK DISSECTION:
METASTATIC SQUAMOUS CARCINOMA IN 1 OF 13 REGIONAL LYMPH NODES WITH
FOCAL EXTENSION INTO EXTRA-NODAL CONNECTIVE TISSUE DISTRIBUTED
AS FOLLOWS:
Three submental/submandibular lymph nodes, no tumor present.
METASTATIC SQUAMOUS CARCINOMA IN ONE OF TWO SUBDIGASTRIC
LYMPH NODES WITH FOCAL EXTENSION INTO EXTRA-NODAL CONNECTIVE
TISSUE.
Eight midjugular lymph nodes, no tumor present.
Submandibular gland, no tumor present.
- (B) "RIGHT BASE OF TONGUE":
Focal mucosal ulceration; there is no diagnostic evidence of
malignancy.
- (C) "SUBTOTAL GLOSSECTOMY":
INVASIVE GRADE I-II SQUAMOUS CARCINOMA; RESECTION MARGINS FREE OF
TUMOR. (SEE COMMENT)

COMMENT

The morphological features of this neoplasm are those of a relatively low-grade (i.e., grade I-II) invasive, keratinizing squamous carcinoma. Tumor invades underlying submucosal connective tissue, superficial muscle and deep muscle. Tumor forms an ulcerated 2.5 x 2.0 cm mass that invades to a depth of approximately 1.5 cm. Peri-neural invasion is present. There are morphological features strongly suggestive of lympho-vascular invasion by tumor. The final resection margins are free of tumor.

SPECIMEN

- (A) RIGHT SUPRAOMOHYOID NECK DISSECTION:
(B) "RIGHT BASE OF TONGUE":
(C) "SUBTOTAL GLOSSECTOMY":

SNOMED CODES

T-53000, M-80703

ICD-0-3

carcinoma, squamous cell, keratinizing, nos 8071/3

Site: tongue, nos C02.9

hw

10/1/12

9/9/12

Source: NCI Genomic Data Commons file fa4d4d9c-ab19-46be-970f-c44ebb56ce59 (TCGA-CV-A45R.6F3E617E-2DF0-4822-A764-3A1DF7F2748F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).